Gene-level copy-number profile of tumor specimen TCGA-CH-5751-01A from TCGA case TCGA-CH-5751, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.3 years (24,957 days).
Specimen TCGA-CH-5751-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.06d9436a-ff8b-4c5f-a60c-f434f6d5aaf2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5751-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 416 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/caadd123-aefb-4da7-bf09-0ca279c468a3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,189; copy number 1: 8,668; copy number 2: 34,924; copy number 3: 10,745; copy number 4: 1,184; copy number 5: 125; copy number 6: 866; copy number 7: 192; copy number 8: 204; copy number 9: 33; copy number 16: 72; copy number 17: 3; copy number 24: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5751-01A-11D-1574-01): tumor purity 0.54, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 817 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:55,424,854–80,256,048, 426 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:150,584–4,994,972, 63 genes (within-gene range 0–1) (broad region; genes not listed).
- chr8:12,945,642–26,382,953, 227 genes (broad region; genes not listed).
- chr8:28,345,590–32,855,666, 84 genes (within-gene range 0–1) (broad region; genes not listed).
- chr8:39,309,909–39,522,852, 3 genes: AC105185.1, ADAM5, ADAM3A.
- chr12:7,812,512–7,972,759, 10 genes (within-gene range 0–2): SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–1): AC092821.1, AC092821.2.
- chr22:50,059,391–50,085,426, 1 gene: MLC1.
- chr22:50,092,745–50,096,437, 1 gene: AL034546.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,497 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 9 (within-gene range 2–9): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr3:86,816,740–88,168,729, 19 genes, copy number 5: AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38.
- chr4:69,199,951–69,216,635, 2 genes, copy number 6 (within-gene range 2–6): UGT2B11, AC114797.1.
- chr7:4,130,181–5,513,809, 35 genes, copy number 5 (within-gene range 3–5): AC017000.1, CYP3A54P, AC072054.1, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589.
- chr7:101,362,875–101,559,024, 2 genes, copy number 6 (within-gene range 3–6): COL26A1, AC004965.1.
- chr8:39,522,976–39,580,134, 1 gene, copy number 5 (within-gene range 0–5): AC123767.1.
- chr8:48,710,789–50,796,692, 18 genes, copy number 5–6 (within-gene range 4–6): EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2.
- chr8:51,950,284–52,022,974, 3 genes, copy number 7: AC064807.4, AC064807.2, AC064807.3.
- chr8:57,341,021–58,204,279, 12 genes, copy number 7–8 (within-gene range 4–8): AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26.
- chr8:72,537,225–72,938,349, 1 gene, copy number 17 (within-gene range 4–17): KCNB2.
- chr8:72,732,045–101,076,407, 450 genes, copy number 6–17 (broad region; genes not listed).
- chr8:101,137,959–145,066,685, 675 genes, copy number 6–7 (broad region; genes not listed).
- chr11:54,591,480–56,276,819, 84 genes, copy number 5–7 (broad region; genes not listed).
- chr14:105,546,610–106,666,532, 168 genes, copy number 6 (broad region; genes not listed).
- chr20:1,561,385–1,620,061, 2 genes, copy number 24 (within-gene range 2–24): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 8,103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
